Surgical pathology report (de-identified scan), TCGA case TCGA-FA-A7DS, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Asterand, specimen TCGA-FA-A7DS-01A (Primary Tumor).

[page 1 of 2]
TSS Patient ID:

Surgical Date:

Gross Description: A solid tumor is located in nearby of the nipple, with 4x3x3.5cm in size, firm with a gray surface, irregular border.

Microscopic Description: Tumor cells arrange in diffuse or alveolar, or sheets replace benign tissue. The tumor cells are composed of large transformed lymphoid cells with very hyperchromatic enlarged nuclei. Tumor cells are oval or round in shape with defined cytoplasm. Nucleoli is single or multiple. Mitotic figures are common. Tumor is invasion of benign breast tissue.

Diagnosis Details: Large B-cell diffuse lymphoma

Comments:

Formatted Path Reports: BREAST TISSUE CHECKLIST

Specimen type: Mastectomy

Specimen size: Not specified

Tumor site: Breast

Tumor size: 4 x 3 x 3.5 cm

Grossly evident lesion: Yes

Histologic type: Diffuse large b-cell lymphoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Lymph nodes: 0/9 positive for metastasis (Axillary 0/9)

Extracapsular invasion of the lymph nodes: Not specified

Margins: Not specified

Nottingham Histologic Score

Tubule formation: Not specified

Nuclear pleomorphism: Not specified

Mitotic count (25x): Not specified

Mitotic count (40x): Not specified

ICD O-3

Lymphoma, diffuse large
B-cell 9680/3

Site ^{ASCF} Breast NOS C50.9
^{path} Breast, central portion C50.1
JW 9/3/13

[page 2 of 2]
Total Nottingham Score: Score cannot be determined

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: CKAE1/AE3(-), CD20(+), CD3(-)

Comments: Right- central

Reviewed Initials:	8/21/13	

Source: NCI Genomic Data Commons file 049e9450-d220-473f-b622-3600fff8053e (TCGA-FA-A7DS.F36A477E-88C9-476A-BF68-61CA129A30A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).